Gene-level copy-number profile of tumor specimen C3L-00356-01 from CPTAC case C3L-00356, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 73.0 years (26,668 days).
Specimen C3L-00356-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bb940262-f3a5-407e-a03f-c1fe53f43b1c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00356-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/57a6e71a-3826-4a80-b357-7a251d38ba07

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,751; copy number 2: 17,488; copy number 3: 19,116; copy number 4: 14,099; copy number 5: 2,755; copy number 6: 860; copy number 7: 660; copy number 8: 127; copy number 9: 1,121; copy number 10: 147; copy number 11: 73; copy number 12: 8; copy number 13: 18; copy number 14: 1; copy number 15: 22; copy number 16: 9; copy number 17: 31; copy number 18: 4; copy number 24: 34; copy number 29: 28; copy number 31: 43.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,326 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,406,527–39,128,927, 26 genes, copy number 8: LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1, SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA.
- chr2:121,726,945–121,736,911, 1 gene, copy number 9 (within-gene range 5–9): NIFK.
- chr3:105,366,909–114,310,288, 149 genes, copy number 7–15 (broad region; genes not listed).
- chr3:114,314,501–114,329,714, 2 genes, copy number 8: AC093010.2, MIR568.
- chr3:136,336,236–136,752,403, 1 gene, copy number 18 (within-gene range 5–29): STAG1.
- chr3:136,609,050–143,856,142, 139 genes, copy number 9–31 (broad region; genes not listed).
- chr3:167,065,831–169,663,775, 27 genes, copy number 10–16 (within-gene range 5–16): PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM.
- chr3:174,377,244–174,378,005, 1 gene, copy number 7: AC069218.1.
- chr3:196,142,525–196,662,004, 29 genes, copy number 8 (within-gene range 6–8): LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS.
- chr7:128,862,042–129,213,545, 19 genes, copy number 7 (within-gene range 3–7): KCP, ATP6V1F, ATP6V1FNB, AC025594.1, IRF5, AC025594.2, TNPO3, RN7SL306P, ODCP, TPI1P2, AC018639.1, AC011005.2, AC011005.3, CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO, AC011005.4.
- chr8:53,712,697–57,289,649, 67 genes, copy number 7 (broad region; genes not listed).
- chr8:68,330,955–145,066,685, 1,168 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:65,455,258–65,592,650, 15 genes, copy number 7 (within-gene range 4–7): AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1.
- chr16:4,616,493–4,847,288, 17 genes, copy number 9 (within-gene range 6–9): MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A, NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP, SEPTIN12, AC020663.4, SMIM22, AC020663.2, ROGDI, GLYR1.
- chr16:11,927,259–11,976,643, 3 genes, copy number 8: NPIPB2, TNFRSF17, UBL5P4.
- chr16:46,469,341–46,851,254, 17 genes, copy number 8: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2.
- chr17:75,406,069–76,271,298, 48 genes, copy number 9: MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL, SRP68, ZACN, GALR2, EXOC7, AC018665.1, MIR6868, FOXJ1, RNF157-AS1, RNF157, ATP5MGP6, ATF4P3, UBALD2.
- chr17:79,848,058–80,542,605, 30 genes, copy number 7–10: AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31.
- chr17:81,480,523–82,065,887, 53 genes, copy number 7: LINC01971, ACTG1, AC139149.1, FSCN2, FAAP100, NPLOC4, Y_RNA, TSPAN10, PDE6G, OXLD1, CCDC137, ARL16, HGS, MIR6786, AC139530.3, AC139530.1, MRPL12, AC139530.2, SLC25A10, GCGR, MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9, AC145207.2, ARHGDIA, AC145207.5, AC145207.6, ALYREF, ANAPC11, NPB, PCYT2, SIRT7, MAFG, AC145207.8, MAFG-DT, PYCR1, AC145207.4, MYADML2, AC145207.1, NOTUM, AC145207.7, ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L.
- chr19:27,638,483–28,125,430, 15 genes, copy number 13: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:28,418,483–41,307,787, 499 genes, copy number 7–17 (within-gene range 2–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 463. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
